TCGA case TCGA-VR-A8EW — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/71f9f567-3687-4e3f-ad20-aed026a5b7e1

Demographics
Sex at birth: male; Race: asian; Country of residence at enrollment: Brazil; Age at index: 57 years; Vital status: Dead; Days to death: 247 days; Country of birth: Brazil.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.4; Tissue or organ of origin: Middle third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,902 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Cancer detection method: Symptomatic; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Middle Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 13.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, preoperative; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 247 days; Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0.
- Barretts esophagus goblet cells present: No; Timepoint: Prior to Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 48 kg; Height: 164 cm; BMI: 17.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 10; Age at onset: 27.
- Alcohol history: Yes; Alcohol drinks per day: 1; Alcohol days per week: 1.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VR-A8EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 70 mg.
  Slide TCGA-VR-A8EW-01A-01-TS1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 60; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-VR-A8EW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VR-A8EW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Sao Paulo; Cancer procurement city: Barretos; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 1; History reflux disease indicator: No; History hpylori infection indicator: Never; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: Yes; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 247 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 247 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 247 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VR-A8EW-01A-11D-A36I-01): tumor purity 0.53, ploidy 6.1, whole-genome doublings 2.
